Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7692, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7692-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

Sections demonstrate a hypercellular glial neoplasm composed of two phenotypic populations of neoplastic cells. The astrocytic component of the tumor consists predominantly of cells with gemistocytic features, including eccentric moderately pleomorphic nuclei and abundant eosinophilic cytoplasm. The oligodendrocytic component of the tumor is characterized by numerous neoplastic cells with round to oval nuclei and prominent perinuclear halos. The two populations of tumor cells in some areas are intermixed and in others areas appear separate. Overall, the cytologic atypia appears moderate. There is a background of microcystic change. The tumor diffusely infiltrates adjacent brain parenchyma. Scattered mitotic figures are seen. Microvascular proliferation is prevalent. Foci of early microvascular necrosis are seen. The low mitotic activity of the tumor (up to 2 mitoses per 10 high power fields) and the moderate degree of pleomorphism would suggest a low grade glioma; however, the presence of prominent microvascular proliferation and foci of early necrosis are concerning for a high grade tumor. A final diagnosis will be issued pending review of MIB-1.

Addendum Discussion:

The MIB-1 labeling index ranges up to 6.9% in the most proliferative regions of tumor. The elevated MIB-1 labeling index, in conjunction with the immunohistochemical features support an oligoastrocytoma with features concerning for early anaplastic progression. The findings of early microvascular necrosis and microvascular proliferation are worrisome for anaplastic progression. The degree of necrosis is not felt to be substantial enough to classify this tumor as a glioblastoma with oligodendroglial differentiation; however, this neoplasm should be closely followed.

Diagnosis:

Oligoastrocytoma with early anaplastic progression. MIB-1 Labeling Index= 6.9%

Source: NCI Genomic Data Commons file 3be4e897-5384-447d-b5d9-34561e90334c (TCGA-HT-7692.C5F0A360-5011-4EDE-B4B5-BBD30B54B21F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).